MMRF case MMRF_2562 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/943dee3d-b01e-440d-81de-35a3bdae1941

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.4 years (24,237 days); ISS stage: II; Days to last known disease status: 584 days (1.6 years); Days to last follow up: 584 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 137 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 255 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 295 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 298 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 2): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL; Immunoglobulin G 28.7 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 3.78 µg/mL; Lactate Dehydrogenase 6.48 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.53 mmol/L; Albumin 42 g/L; Total Protein 8.7 g/dL; Glucose 5.89 mmol/L.
- Day 80 (ECOG 2): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 7.27 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.42 µg/mL; Hemoglobin 8.49 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 10.6 mmol/L.
- Day 185 (ECOG 2): M Protein 2.3 g/dL; Immunoglobulin G 22.8 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.18 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 7.26 mmol/L.
- Day 247 (ECOG 1): M Protein 2.6 g/dL; Immunoglobulin G 32.1 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 8.2 g/dL; Glucose 8.97 mmol/L.
- Day 353 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.38 µg/mL; Lactate Dehydrogenase 8.97 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 5.17 mmol/L.
- Day 501 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 7.84 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 11.5 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 6.6 mmol/L.
- Day 584 (ECOG 2): M Protein 1.3 g/dL; Hemoglobin 7.38 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.48 mmol/L; Albumin 48 g/L; Total Protein 7.5 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -10: Weight: 86 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2562_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2562_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
